Somatic mutation profile of tumor specimen TARGET-30-PASMJG-01A (aliquot TARGET-30-PASMJG-01A-01D) from TARGET case TARGET-30-PASMJG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.8 years (1,765 days).
Specimen TARGET-30-PASMJG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b119fc17-62ee-4f59-9a64-282be0fcc18f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASMJG-10A (Blood Derived Normal), aliquot TARGET-30-PASMJG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4121e79a-c690-4f10-8ba4-fb28c075ca22

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1644A>G p.I548M | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV65950086; called by muse, mutect2
- APPL1 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NKAPD1 | c.48G>A p.R16= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
